Gene-level copy-number profile of tumor specimen ALCH-ADUD-TTP1-A from ALCHEMIST case ALCH-ADUD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 60.8 years (22,204 days).
Specimen ALCH-ADUD-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6bea7ad1-76d7-4783-bb69-3389ab5986be.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADUD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/7386f193-a499-4fbb-ad08-dfe3c46a6c12

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 6,292; copy number 2: 48,728; copy number 3: 3,729; copy number 4: 47; copy number 5: 48; copy number 6: 3; copy number 9: 1; copy number 10: 3; copy number 11: 1; copy number 12: 3; copy number 17: 3; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:12,411,398–12,411,501, 1 gene (within-gene range 0–2): RNU6-843P.
- chr4:1,009,936–1,028,972, 2 genes: FGFRL1, AC019103.1.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.
- chr7:128,830,406–128,859,274, 1 gene (within-gene range 0–2): FLNC.
- chr11:1,828,307–1,837,521, 1 gene: SYT8.
- chr14:105,140,982–105,181,323, 4 genes: JAG2, MIR6765, AL512356.1, NUDT14.
- chr15:55,056,723–55,092,177, 1 gene: AC025272.1.
- chr17:41,619,442–41,640,199, 2 genes: KRT17, KRT42P.
- chr19:1,905,372–1,926,013, 2 genes: SCAMP4, ADAT3.
- chr19:1,952,531–1,954,586, 1 gene (within-gene range 0–1): CSNK1G2-AS1.
- chr19:37,235,507–37,304,395, 2 genes (within-gene range 0–2): AC016590.1, LINC01535.
- chr22:18,605,355–18,611,919, 3 genes: AC023490.1, RN7SKP131, RIMBP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 63 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:112,823,490–114,294,489, 30 genes, copy number 5: AL158212.3, AL158212.4, AL158212.1, TCF7L2, AL158212.2, RPS15AP30, RNU7-165P, AL133482.1, PPIAP39, HABP2, NRAP, CASP7, AL592546.2, PLEKHS1, MIR4483, AL592546.1, DCLRE1A, NHLRC2, AL592546.3, ADRB1, AC022023.2, RNU6-709P, UBE2V1P5, CCDC186, AC022023.1, MIR2110, TDRD1, VWA2, AURKAP2, AC005383.1.
- chr14:18,333,726–18,650,966, 17 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr21:43,414,483–43,479,534, 4 genes, copy number 5–11: SIK1, LINC00319, LINC00313, AP001048.1.
- chr21:44,217,014–44,244,993, 3 genes, copy number 12: ICOSLG, AP001059.2, AP001059.1.
- chr22:18,400,407–18,530,573, 7 genes, copy number 10–20: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, TMEM191B.
- chr22:18,636,445–18,653,617, 2 genes, copy number 6: CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 3,485. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
